Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BV, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BV-01A (Primary Tumor).

HIIPAA Discrepancy		☒

10/15/11

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1) TOTAL THYROID AND CENTRAL NECK (TOTAL THYROIDECTOMY & CENTRAL NECK DISSECTION):

SPECIMEN TYPE:

Total thyroidectomy and central neck dissection

TUMOR SITE:

Left lobe

105-0-3
Carcinoma, papillary, thyroid
8260/3

HISTOLOGIC TYPE:

Papillary carcinoma

Site: thyroid, NUS C73.9

hw
10/15/11

TUMOR SIZE (LARGEST NODULE):

Greatest dimension: 4.0 cm

FOCALITY:

Unifocal

LYMPH NODES (ALL PARTS):

Metastatic carcinoma in 2 of 17 lymph nodes.

EXTENT OF INVASION (STAGING) PRIMARY TUMOR:

pT2: Tumor >2.0 cm but less than or equal to 4.0 cm, limited to thyroid

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to Level VI (pretracheal, paratracheal, and prelaryngeal/Delphian) nodes

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved.

Distance of invasive carcinoma from nearest margin: 1.0 mm.

Specify margin: Inked anterior and posterior margins

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Chronic lymphocytic thyroiditis

Source: NCI Genomic Data Commons file d5b2497c-0e32-41ea-987a-e86211418e88 (TCGA-ET-A3BV.97DA3EC1-87E4-46BA-AEBB-255DA0A24778.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).